Somatic mutation profile of tumor specimen C3L-04250-54 (aliquot CPT0260060002) from CPTAC case C3L-04250, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 72.8 years (26,599 days).
Specimen C3L-04250-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6567fb6e-0680-4903-8d99-610c0ea27c3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04250-50 (Buccal Cell Normal), aliquot CPT0260050003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9294a918-0b72-438b-87f9-79d3c7761119

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.2453G>A p.S818N | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.034); catalogued as rs769496934; called by muse, varscan2
- FOXA1 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1198728189; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, varscan2
- WT1 | c.1074dup p.V359Cfs*14 | Frame Shift Ins (INS) | VAF 221/480 reads (46%) | catalogued as COSV60068321, COSV60085606, COSV60086731; called by mutect2, varscan2
- DNAH9 | c.9983C>G p.T3328R | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TET2 | c.2558_2564del p.L853Qfs*18 | Frame Shift Del (DEL) | VAF 179/482 reads (37%) | called by mutect2, varscan2
- AS3MT | c.414G>A p.K138= | Silent (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- FCHSD1 | c.351C>T p.S117= | Silent (SNP) | VAF 18/167 reads (11%) | catalogued as rs762851085, COSV53354756; called by muse, mutect2, varscan2
